EXCEPTIONAL_RESPONDERS case ER-AC0F — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/279ba00e-d313-4bc2-9858-0eca1ae942dd

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive.

Diagnoses (2)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 58.2 years (21,260 days); Year of diagnosis: 2007; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Days to last follow up: 2,723 days (7.5 years); Days to best overall response: 699 days (1.9 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Paclitaxel; Days to treatment start: 20 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 20 days; Days to treatment end: 2,842 days (7.8 years).
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 54.9 years (20,069 days); AJCC pathologic stage: Stage IIIA.

Follow-up (1 entry)
- Days to follow up: 2,723 days (7.5 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 0 days; Days progression-free: 2,723 days (7.5 years).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AC0F-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AC0F-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-AC0F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AC0F-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 10; Percent normal cells: 94; Percent necrosis: 0; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-AC0F-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AC0F-TTP2-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 40; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
